CCDI case PBBZXZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/750c088b-97a9-4fec-8819-11417bbc46df

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 9.5 years (3,473 days).

Biospecimens (3 samples)
- Sample 0DM4X5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM4XJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DM4XX: Tissue type: Tumor; Specimen type: Solid Tissue.
